Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9LY, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9LY-01A (Primary Tumor).

[page 1 of 3]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

Gross description:

1. (Prostate gland): Prostate gland: Weight: 24 g, Volume: 19 ml, Size: 2.4 x 4.5 x 3.6 cm. Adherent seminal vesicles and deferent duct: right side: 2.6 cm, left side: 2.4 cm. The surface is marked with green ink on the right side, blue ink on the left side. On the right recto-lateral surface a 3.7 x 2.6 cm measuring tissue defect marked with yellow ink. Apical peri-urethral a funnel shaped 1.2 x 1 cm tissue defect marked with red ink. Total of the cross sections: 1.2 cm.
2. (Lymph nodes, right side): 4.5 x 3.5 x 1.2 cm measuring adipose tissue containing 9 nodes measuring up to 3.1 cm.
3. (Lymph nodes, left side): 4.5 x 5 x 1.2 cm measuring adipose tissue containing 5 nodes measuring up to 3.5 cm.

Microscopy:

1. Apex right and left: Right 7 tissue blocks, left 6 tissue blocks (total 13 tissue blocks). 3 cross sections: Right 10 tissue blocks, left 12 tissue blocks (total 22 tissue blocks). Basis right and left: Right 6 tissue blocks, left 6 tissue blocks (total 12 tissue blocks). Seminal vesicles right and left: Right 4 tissue blocks, left 4 tissue blocks (total 8 tissue blocks). Deferent ducts right and left: Right 1 tissue block, left 1 tissue block (total 2 tissue blocks).
2. Frozen lymph nodes right: 12 tissue blocks.
3. Frozen lymph nodes left: 8 tissue blocks.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
JW 1/23/14

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 4+5=9, (Gleason 4: 60%, Gleason 5: 35%, Gleason 3: 5%). Tumor involves both lobes with the main focus on the left side. Maximum tumor diameter: 22 mm. Perineural invasion. Tumor infiltration into peri-prostatic adipose tissue in 2 tissue blocks with the main focus around the seminal vesicles (maximum invasion length 0.3 mm, maximal invasion depth 0.2 mm). Tumor infiltration into both seminal vesicles. Positive surgical margin in 2 blocks (contact length 0.7 mm basal left and 0.4 mm basal right side; Gleason 4).

Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Tumor-free deferent ducts.

2. (Lymph nodes, right side): Eight tumor-free lymph nodes (0/8).
3. (Lymph nodes, left side): One lymph node metastasis (4.2 mm) in three lymph nodes (1/3).

[page 2 of 3]
Tumor classification

(in consideration of the intraoperative frozen-section and immunohistochemical analyses):

pT3b, Gleason 4+5=9 (Gleason 4: 60%, Gleason 5: 35%, Gleason 3: 5%), maximum tumor diameter: 22 mm, tumor volume approx. 17.2 ml (Gleason 4: 10.3 ml, Gleason 5: 6.0 ml, Gleason 3: 0.9 ml), pN1 (1/11), L1, V0, R1

Comments:

Positive surgical margin in tissue blocks BR2A and BL1A.

Tumor infiltration into peri-prostatic adipose tissue in blocks SBR1 and SBL3.

The preceding intraoperative frozen section revealed more adenocarcinoma on the right side with positive surgical margin. The left side was not examined in the intraoperative frozen section. The resected right neurovascular bundle showed minor tumor infiltration. It is not clear whether the resected neurovascular bundle covers the positive surgical margin on the right side. However, the tumor has to be staged as R1 due to the positive surgical margin on the left side. Furthermore, immunohistochemical analyses (D2-40, CD31) on tissue blocks SBL1 and SBL1 revealed distinctive lymphatic invasion. No venous invasion found.

One macroscopic image for tumor mapping.

*Per dx discrepancy, TCGA
tumor Gleason is 5 + 4.*

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

12/2015

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason 4+5	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Gleason 5+4	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Frozen sample tissue block submitted to TCGA has a different Gleason score than the frozen tissue block that was used for diagnosis.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 6ea4a3b4-9426-482b-b0a9-5d8cc55b435e (TCGA-ZG-A9LY.E4B3E97A-9587-47C2-BE35-C67B268CA133.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).